Somatic mutation profile of cancer-model specimen HCM-CSHL-0768-C56-85O (3D Organoid, passage 7; aliquot HCM-CSHL-0768-C56-85O-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0768-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage II; Tumor grade: High Grade.
Specimen HCM-CSHL-0768-C56-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f0da4af-70e9-4c75-85a4-30bf5c209032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0768-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0768-C56-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/856d67ba-65b0-4d76-88eb-ad9d04383f84

The open-access MAF lists 50 somatic variants for this specimen: 34 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 15, Nonsense Mutation 7, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 275/275 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC5 | c.3799C>T p.R1267* | Nonsense Mutation (SNP) | VAF 237/559 reads (42%) | catalogued as COSV55593485; called by muse, mutect2, varscan2
- AC099489.1 | c.4111C>T p.R1371* | Nonsense Mutation (SNP) | VAF 24/348 reads (7%) | catalogued as rs1019283750; called by muse, mutect2
- ADGRB3 | c.2084C>G p.S695* | Nonsense Mutation (SNP) | VAF 9/149 reads (6%) | catalogued as COSV65391510; called by muse, mutect2
- APBA2 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 106/1082 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as COSV68788287; called by muse, mutect2
- ATP10A | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 153/420 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs1381646630, COSV63519072; called by muse, mutect2, varscan2
- GRK3 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748016202; called by muse, mutect2, varscan2
- LRP1B | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 39/504 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs921851032, COSV67214705; called by muse, mutect2
- NPIPB15 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 71/462 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs375786148; called by muse, varscan2
- PCNT | c.5266A>G p.M1756V | Missense Mutation (SNP) | VAF 337/585 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs769923170; called by muse, mutect2, varscan2
- PHYKPL | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 145/449 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs757976712, COSV57425767; called by muse, mutect2, varscan2
- RINL | c.1519G>A p.A507T (on ENST00000591812 / NM_001195833.2; = p.A393T on NM_198445.4) | Missense Mutation (SNP) | VAF 381/729 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1173818428; called by muse, mutect2, varscan2
- SAMD9L | c.4016G>A p.R1339K | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as rs1346276637; called by muse, mutect2, varscan2
- TAT | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 29/353 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63533640; called by muse, mutect2
- WNT4 | c.977G>A p.C326Y | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323167318; called by muse, mutect2, varscan2
- AKR7A2 | c.118T>G p.S40A | Missense Mutation (SNP) | VAF 605/606 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ATF6 | c.874G>C p.V292L | Missense Mutation (SNP) | VAF 121/353 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAS1 | c.1660G>A p.G554R | Missense Mutation (SNP) | VAF 242/747 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- CCDC86 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 132/233 reads (57%) | called by muse, mutect2, varscan2
- CDK6 | c.77A>T p.K26M | Missense Mutation (SNP) | VAF 42/834 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2
- CSMD3 | c.8786A>T p.K2929I (on ENST00000297405 / NM_001363185.1; = p.K2760I on NM_052900.3) | Missense Mutation (SNP) | VAF 188/787 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ECHDC3 | c.847_874del p.G283Rfs*49 | Frame Shift Del (DEL) | VAF 153/316 reads (48%) | called by mutect2, pindel, varscan2
- ENPP7 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 52/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FASTKD2 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 19/290 reads (7%) | called by muse, mutect2
- GOLGA6C | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 125/440 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- IPP | c.577_582del p.S193_I194del | In Frame Del (DEL) | VAF 127/471 reads (27%) | called by mutect2, pindel, varscan2
- LCE2D | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 70/879 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- MUC5B | c.13823G>T p.S4608I | Missense Mutation (SNP) | VAF 241/914 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R2 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 442/901 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAV1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 168/168 reads (100%) | called by muse, mutect2, varscan2
- SI | c.2912C>A p.A971E | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.057); called by muse, mutect2
- SRFBP1 | c.1070A>T p.N357I | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- THSD7A | c.337A>T p.K113* | Nonsense Mutation (SNP) | VAF 127/424 reads (30%) | called by muse, mutect2, varscan2
- TNS2 | c.1221G>T p.W407C (on ENST00000314250 / NM_170754.4; = p.W417C on NM_015319.2) | Missense Mutation (SNP) | VAF 338/338 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS9 | c.2991C>T p.N997= | Silent (SNP) | VAF 144/585 reads (25%) | called by muse, mutect2, varscan2
- ADCY3 | c.1824C>T p.T608= | Silent (SNP) | VAF 39/423 reads (9%) | catalogued as rs910761786; called by muse, mutect2
- CD3E | c.586C>A p.R196= | Silent (SNP) | VAF 332/566 reads (59%) | called by muse, varscan2
- EFR3A | c.1438T>C p.L480= | Silent (SNP) | VAF 684/940 reads (73%) | called by muse, mutect2, varscan2
- FES | c.1788C>T p.L596= | Silent (SNP) | VAF 126/397 reads (32%) | called by muse, mutect2, varscan2
- HCN3 | c.1290C>T p.A430= | Silent (SNP) | VAF 171/528 reads (32%) | called by muse, mutect2, varscan2
- HTR3D | c.1233C>T p.H411= (on ENST00000382489 / NM_001163646.2; = p.H236= on NM_182537.3) | Silent (SNP) | VAF 196/865 reads (23%) | catalogued as rs550781623; called by muse, mutect2, varscan2
- IL1F10 | c.324C>T p.S108= | Silent (SNP) | VAF 202/634 reads (32%) | catalogued as rs375615196; called by muse, mutect2, varscan2
- OR2A5 | c.783C>A p.A261= | Silent (SNP) | VAF 134/456 reads (29%) | catalogued as COSV68738975; called by muse, mutect2
- PPM1H | c.930G>A p.T310= | Silent (SNP) | VAF 29/225 reads (13%) | catalogued as rs370367276; called by muse, mutect2, varscan2
- R3HCC1L | c.786A>T p.G262= | Silent (SNP) | VAF 264/435 reads (61%) | catalogued as rs1279143201, COSV54404105; called by muse, mutect2, varscan2
- RHOT2 | c.150G>A p.K50= | Silent (SNP) | VAF 60/523 reads (11%) | catalogued as rs778695005; called by muse, mutect2, varscan2
- TOP1MT | c.579G>A p.P193= | Silent (SNP) | VAF 177/1710 reads (10%) | catalogued as rs368057294; called by muse, mutect2, varscan2
- ZNF606 | c.1650G>A p.R550= | Silent (SNP) | VAF 28/440 reads (6%) | catalogued as rs1027224174; called by muse, mutect2
- ZNF670 | c.306A>G p.P102= | Silent (SNP) | VAF 292/450 reads (65%) | catalogued as rs763924657; called by muse, mutect2, varscan2
- AP1S3 | c.292-4947G>A | Intron (SNP) | VAF 116/359 reads (32%) | called by muse, mutect2, varscan2
